Somatic mutation profile of tumor specimen f6c215ea-5381-4521-bb61-be8e97 (aliquot f6c215ea-5381-4521-bb61-be8e97_D6) from CPTAC case 04OV018, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen f6c215ea-5381-4521-bb61-be8e97: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f983dc7-830f-4c87-97be-ec2a06f108f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5d9282ce-5954-476d-ba32-aa73d0 (Blood Derived Normal), aliquot 5d9282ce-5954-476d-ba32-aa73d0_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c080e32-0ba8-437e-b8b3-a6efe546a633

The open-access MAF lists 121 somatic variants for this specimen: 85 protein-altering or splice-affecting, 17 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 17, Intron 8, Frame Shift Del 5, 5'UTR 3, 3'UTR 3, Splice Site 2, Nonsense Mutation 2, In Frame Del 2, RNA 2, 3'Flank 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 70/155 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.904); catalogued as COSV56016952; called by muse, mutect2, varscan2
- AFF3 | c.1444A>C p.I482L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs763715646; called by muse, mutect2, varscan2
- CHD7 | c.5469G>A p.M1823I | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as COSV71115215; called by muse, mutect2, varscan2
- COL4A4 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs754523110; called by muse, mutect2, varscan2
- ESPL1 | c.4675C>T p.R1559W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs552155175, COSV57763272; called by muse, mutect2
- GABRA5 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs548864677; called by muse, mutect2, varscan2
- IRS4 | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 55/327 reads (17%) | catalogued as COSV100929436; called by muse, mutect2, varscan2
- KIF4B | c.2684G>C p.C895S | Missense Mutation (SNP) | VAF 197/399 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs762787846; called by muse, mutect2, varscan2
- LUC7L2 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.92); catalogued as COSV54923649; called by muse, mutect2, varscan2
- MCPH1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs761775509; called by muse, mutect2, varscan2
- NLGN3 | c.826G>T p.G276W (on ENST00000358741 / NM_181303.2; = p.G256W on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704775; called by muse, mutect2, varscan2
- OBSCN | c.7828C>T p.R2610W | Missense Mutation (SNP) | VAF 223/432 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as rs569655273; called by muse, mutect2, varscan2
- PDZRN3 | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs761619340; called by muse, mutect2, varscan2
- TENM1 | c.3113C>A p.T1038N | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV64443526; called by muse, mutect2, varscan2
- TLR4 | c.1082A>G p.N361S (on ENST00000355622 / NM_138554.5; = p.N321S on NM_003266.4) | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.312); catalogued as rs749495848; called by muse, varscan2
- TTN | c.28567C>T p.R9523C (on ENST00000591111; = p.R8596C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/131 reads (39%) | PolyPhen probably damaging (0.998); catalogued as rs369990929, COSV60387529; called by muse, mutect2, varscan2
- TYW1 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144746147; called by muse, mutect2, varscan2
- UNC93A | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs375435906; called by muse, mutect2, varscan2
- ZDHHC11 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 53/670 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV52074086, COSV99362389; called by muse, mutect2
- ZNF160 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.228); catalogued as COSV62001391; called by muse, mutect2, varscan2
- ABCC10 | c.696G>T p.L232F (on ENST00000372530 / NM_001198934.2; = p.L189F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ABHD16B | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ALOX15 | c.1649G>C p.W550S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANTXRL | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2
- B4GALNT3 | c.2828del p.G943Afs*2 | Frame Shift Del (DEL) | VAF 95/271 reads (35%) | called by mutect2, pindel, varscan2
- BRD8 | c.1239del p.F413Lfs*15 (on ENST00000254900 / NM_139199.2; = p.F486Lfs*15 on NM_006696.4) | Frame Shift Del (DEL) | VAF 80/190 reads (42%) | called by mutect2, varscan2
- CAPN5 | c.842A>T p.E281V (on ENST00000456580; = p.E241V on NM_004055.5) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC180 | c.3493C>A p.L1165M | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- COPB1 | c.527T>G p.L176R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CTAGE6 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CUL4B | c.975-1G>A p.X325_splice | Splice Site (SNP) | VAF 67/158 reads (42%) | called by muse, mutect2, varscan2
- DNAH10 | c.894C>A p.D298E (on ENST00000409039; = p.D237E on NM_207437.3) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- DOCK11 | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2
- DTNA | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHD1 | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ELAPOR2 | c.769C>T p.L257F (on ENST00000450689 / NM_001142749.3; = p.L90F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM53C | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 87/598 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- FEM1B | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 65/480 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- FRMD3 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMNC | c.384+1G>C p.X128_splice | Splice Site (SNP) | VAF 52/167 reads (31%) | called by muse, mutect2, varscan2
- GPRIN3 | c.1814_1816dup p.L605_S606insM | In Frame Ins (INS) | VAF 58/280 reads (21%) | called by pindel, varscan2
- GRXCR2 | c.615T>G p.S205R | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HDLBP | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- HIPK4 | c.66del p.F22Lfs*4 | Frame Shift Del (DEL) | VAF 125/313 reads (40%) | called by mutect2, pindel, varscan2
- HSH2D | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IL3RA | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- KCNF1 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNK5 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KLHDC7A | c.908A>C p.Q303P | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT12 | c.431G>C p.R144P | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LOXHD1 | c.4067G>A p.R1356K | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRRN4CL | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- LSM10 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LZTS1 | c.1329G>T p.K443N | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MDH2 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- MTREX | c.715G>C p.G239R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN3 | c.1990C>G p.R664G (on ENST00000335750 / NM_001330195.2; = p.R291G on NM_004796.6) | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OAS2 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- P3H3 | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2
- PALM | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCSK5 | c.3209C>A p.T1070N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAT | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS54 | c.475_477del p.P159del | In Frame Del (DEL) | VAF 44/238 reads (18%) | called by pindel, varscan2
- RAD21 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RCAN2 | c.46T>C p.C16R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- REPIN1 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SENP7 | c.149_177del p.K50Tfs*11 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- SLC17A2 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- SLC26A1 | c.1607del p.G536Afs*87 | Frame Shift Del (DEL) | VAF 107/342 reads (31%) | called by mutect2, pindel, varscan2
- SNX14 | c.1864G>T p.V622L (on ENST00000314673 / NM_001350535.1; = p.V569L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SOD3 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ST7 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 60/99 reads (61%) | called by muse, mutect2, varscan2
- STARD9 | c.7715G>C p.G2572A | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.076); called by muse, varscan2
- STRIP1 | c.2274T>G p.D758E | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TCAF1 | c.38_46del p.N13_V15del | In Frame Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- TIE1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TRIM24 | c.1138C>G p.R380G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- TTN | c.37570C>G p.L12524V (on ENST00000591111; = p.L5100V on NM_003319.4) | Missense Mutation (SNP) | VAF 41/256 reads (16%) | PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UBR2 | c.4319G>T p.G1440V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by mutect2, varscan2
- UCP3 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- XKR7 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZKSCAN8 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF804A | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZSCAN2 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ADCY6 | c.2157C>T p.S719= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as rs1262720914; called by muse, mutect2, varscan2
- ADRA1B | c.318G>A p.E106= | Silent (SNP) | VAF 19/365 reads (5%) | called by muse, mutect2
- COL1A2 | c.2253T>G p.G751= | Silent (SNP) | VAF 98/704 reads (14%) | called by muse, mutect2, varscan2
- DNAH8 | c.12540G>A p.G4180= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- FAM71F1 | c.321G>A p.S107= | Silent (SNP) | VAF 80/166 reads (48%) | catalogued as rs755432505; called by muse, mutect2, varscan2
- FUT2 | c.543C>T p.F181= | Silent (SNP) | VAF 21/554 reads (4%) | called by muse, mutect2
- LRRC30 | c.399G>C p.P133= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as rs1320468989; called by muse, mutect2
- LTB | c.504C>A p.G168= | Silent (SNP) | VAF 51/230 reads (22%) | called by muse, mutect2, varscan2
- MZF1 | c.621T>G p.S207= | Silent (SNP) | VAF 78/273 reads (29%) | called by muse, mutect2, varscan2
- NLRP6 | c.1644C>T p.F548= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV56459619; called by muse, mutect2, varscan2
- OR2G2 | c.273C>T p.P91= | Silent (SNP) | VAF 15/311 reads (5%) | catalogued as rs1285289772, COSV60742521; called by muse, mutect2
- PRX | c.3867C>T p.A1289= | Silent (SNP) | VAF 64/418 reads (15%) | catalogued as rs759245840, COSV99397003; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHROOM3 | c.3150G>A p.P1050= | Silent (SNP) | VAF 99/399 reads (25%) | catalogued as rs746539386; called by muse, mutect2, varscan2
- SLC19A2 | c.1398C>T p.I466= | Silent (SNP) | VAF 78/458 reads (17%) | catalogued as rs370262388; called by muse, mutect2, varscan2
- SLC25A53 | c.546G>T p.L182= | Silent (SNP) | VAF 70/316 reads (22%) | called by muse, mutect2, varscan2
- SLC30A3 | c.430C>T p.L144= | Silent (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- ZNF335 | c.81G>C p.L27= | Silent (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- AC010507.1 | chr19:200598 G>T | 3'Flank (SNP) | VAF 40/396 reads (10%) | called by muse, varscan2
- ARHGEF7 | c.1014-1945C>T | Intron (SNP) | VAF 70/248 reads (28%) | called by muse, mutect2, varscan2
- ATE1 | c.942+989A>G | Intron (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- CALCB | c.-12G>A | 5'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- CCL18 | c.-18C>G | 5'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- DST | c.4297-4903A>G | Intron (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- GHRH | c.*19G>A | 3'UTR (SNP) | VAF 44/98 reads (45%) | catalogued as rs375615628; called by muse, mutect2, varscan2
- HERC2P3 | n.885G>T | RNA (SNP) | VAF 47/422 reads (11%) | called by muse, mutect2, varscan2
- HSD17B10 | c.-8G>A | 5'UTR (SNP) | VAF 86/330 reads (26%) | catalogued as rs1556895076; called by muse, varscan2
- INTS11 | c.429+411G>A | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- LINC00470 | n.1361-2499A>G | Intron (SNP) | VAF 29/142 reads (20%) | called by muse, mutect2, varscan2
- MIR548I4 | n.63A>T | RNA (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- MPHOSPH9 | c.*1G>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- PALLD | c.2622+28G>T | Intron (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- PIEZO2 | c.7742+45C>T | Intron (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- PISD | c.*80C>A | 3'UTR (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- PRKCSH | c.79+46G>T | Intron (SNP) | VAF 68/474 reads (14%) | called by muse, mutect2, varscan2
- TLE5 | chr19:3062717 C>T | 5'Flank (SNP) | VAF 27/38 reads (71%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071847 G>C | 3'Flank (SNP) | VAF 40/335 reads (12%) | called by muse, mutect2, varscan2
